Gene-level copy-number profile of tumor specimen CDDP-ABJP-TTP1-B from CDDP_EAGLE case CDDP-ABJP, project CDDP_EAGLE-1: CDDP Integrative Analysis of Lung Adenocarcinoma (Phase 2). Sex at birth: male; Vital status: Alive; Primary diagnosis: Adenocarcinoma, NOS; Tissue or organ of origin: Upper lobe, lung; AJCC pathologic stage: Stage IB; Age at diagnosis: 71 years.
Specimen CDDP-ABJP-TTP1-B: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Preservation method: Snap Frozen.
Source: NCI Genomic Data Commons open-access Gene Level Copy Number file cbba3884-99ca-472a-86fb-33a843e5e149.wgs.ASCAT.gene_level.copy_number_variation.tsv, workflow AscatNGS on whole-genome sequencing of the tumor/normal pair, germline comparator CDDP-ABJP-NB1-A (blood derived normal); Data Release 46.0 - August 10, 2026. Values are absolute (integer) total copy numbers per gene for 60,623 GENCODE v36 genes, of which 1,752 have no estimate.
https://portal.gdc.cancer.gov/files/73e827f8-fc86-40e0-a577-735553e1719f

Most common (modal) total copy number across autosomal genes: 2 — the diploid value.
Genes by total copy number (all chromosomes): copy number 0: 63; copy number 1: 658; copy number 2: 18,816; copy number 3: 10,643; copy number 4: 14,124; copy number 5: 10,204; copy number 6: 1,613; copy number 7: 1,184; copy number 8: 653; copy number 9: 198; copy number 10: 266; copy number 11: 279; copy number 12: 61; copy number 13: 50; copy number 14: 50; copy number 15: 9.

Homozygous deletions (total copy number 0; autosomes only): 63 genes in 33 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr2:16,523,176–16,555,564, 2 genes (within-gene range 0–3): AC104623.1, AC104623.2.
- chr3:36,169,767–36,170,448, 1 gene: RFC3P1.
- chr4:10,238,213–10,238,235, 1 gene: AC006499.8.
- chr4:27,217,479–27,282,225, 3 genes (within-gene range 0–2): LINC02261, Y_RNA, AC024132.3.
- chr4:42,892,396–43,030,658, 2 genes: RN7SKP82, GRXCR1.
- chr4:142,023,160–142,847,432, 5 genes (within-gene range 0–2): INPP4B, RPL5P13, LSM3P4, AC139720.2, AC139720.1.
- chr4:144,109,303–144,140,751, 1 gene (within-gene range 0–1): GYPA.
- chr4:144,505,900–144,509,001, 1 gene: AC106871.1.
- chr4:146,706,638–146,975,457, 3 genes: TTC29, AC092435.2, AC092435.1.
- chr4:148,819,351–149,278,123, 6 genes: AC093648.1, AC002460.1, RNU7-197P, AC108156.1, LINC02430, LINC02355.
- chr4:151,949,338–151,991,925, 3 genes: AC097375.4, AC097375.3, RNA5SP169.
- chr4:155,173,716–155,381,694, 1 gene (within-gene range 0–2): AC097467.3.
- chr4:155,286,162–155,381,239, 3 genes (within-gene range 0–2): AC097467.1, MAP9, YWHAEP4.
- chr4:170,343,089–170,605,450, 3 genes: LINC02512, AC074255.1, HSP90AA6P.
- chr4:171,289,475–171,298,267, 1 gene: LINC02504.
- chr5:45,890,216–45,895,970, 1 gene: AC122694.1.
- chr5:145,001,853–145,005,789, 1 gene: NAMPTP2.
- chr5:155,491,336–155,493,598, 1 gene: AC008725.1.
- chr8:24,384,285–24,406,013, 1 gene (within-gene range 0–2): ADAMDEC1.
- chr8:36,378,069–36,779,209, 3 genes (within-gene range 0–1): AC090809.1, RPL23P10, RNA5SP264.
- chr8:43,672,823–43,674,591, 2 genes: AC139365.2, AC139365.1.
- chr10:88,759,982–88,820,546, 3 genes: LIPN, RCBTB2P1, LIPM.
- chr11:50,409,042–50,422,316, 1 gene: AC024405.1.
- chr11:87,917,948–87,917,999, 1 gene: AP000676.1.
- chr12:41,829,898–41,932,592, 2 genes (within-gene range 0–2): AC090630.1, AC006197.1.
- chr12:42,929,848–42,967,353, 2 genes: AC068802.1, AC012038.2.
- chr13:53,207,831–53,801,489, 1 gene (within-gene range 0–2): AL356295.1.
- chr13:53,345,211–53,410,880, 2 genes: AL450423.1, ZNF646P1.
- chr14:23,791,930–23,792,236, 1 gene: RN7SKP205.
- chr15:22,056,709–22,057,638, 1 gene (within-gene range 0–3): OR4H6P.
- chr15:22,094,522–22,095,472, 1 gene (within-gene range 0–3): OR4N4.
- chr16:7,726,841–7,726,951, 1 gene: AC005774.1.
- chr18:41,341,319–41,632,185, 2 genes: AC079052.1, KC6.

Amplified relative to the modal value (total copy number ≥ 5, i.e. more than twice the modal value of 2; autosomes only): 14,567 genes in 176 contiguous regions (the 40 largest listed; coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr1:121,519,112–157,640,301, 642 genes, copy number 5–6 (broad region; genes not listed).
- chr1:157,925,065–160,647,295, 111 genes, copy number 5 (broad region; genes not listed).
- chr1:160,796,074–164,899,296, 111 genes, copy number 5 (within-gene range 3–5) (broad region; genes not listed).
- chr1:177,923,956–199,080,975, 292 genes, copy number 5–12 (broad region; genes not listed).
- chr1:199,752,491–208,255,376, 259 genes, copy number 5 (broad region; genes not listed).
- chr1:208,697,369–213,794,587, 105 genes, copy number 5–7 (broad region; genes not listed).
- chr1:213,983,181–248,937,043, 726 genes, copy number 5–7 (within-gene range 4–7) (broad region; genes not listed).
- chr2:31,173,056–37,435,608, 87 genes, copy number 5 (broad region; genes not listed).
- chr2:60,336,446–79,123,409, 399 genes, copy number 5–7 (broad region; genes not listed).
- chr2:79,866,495–89,600,680, 207 genes, copy number 5 (broad region; genes not listed).
- chr2:89,959,979–114,420,302, 528 genes, copy number 5 (broad region; genes not listed).
- chr2:126,308,494–135,725,270, 237 genes, copy number 5–8 (within-gene range 4–8) (broad region; genes not listed).
- chr2:145,826,285–177,265,515, 423 genes, copy number 5–8 (within-gene range 5–9) (broad region; genes not listed).
- chr2:177,392,768–210,679,107, 510 genes, copy number 5–9 (within-gene range 5–10) (broad region; genes not listed).
- chr3:107,220,744–117,139,389, 147 genes, copy number 6–8 (within-gene range 3–9) (broad region; genes not listed).
- chr3:116,921,328–132,285,410, 321 genes, copy number 5–8 (within-gene range 3–8) (broad region; genes not listed).
- chr3:132,175,402–144,048,719, 206 genes, copy number 5–8 (within-gene range 4–8) (broad region; genes not listed).
- chr3:148,279,682–198,123,232, 878 genes, copy number 6–15 (within-gene range 3–17) (broad region; genes not listed).
- chr5:16,373,361–37,953,827, 288 genes, copy number 5–8 (within-gene range 3–8) (broad region; genes not listed).
- chr5:50,603,229–55,233,608, 76 genes, copy number 5 (broad region; genes not listed).
- chr7:4,130,181–8,262,687, 112 genes, copy number 5 (within-gene range 4–5) (broad region; genes not listed).
- chr7:9,634,270–31,708,455, 341 genes, copy number 5–9 (broad region; genes not listed).
- chr7:47,052,793–57,837,046, 209 genes, copy number 5–6 (broad region; genes not listed).
- chr7:91,940,862–95,540,233, 72 genes, copy number 5–6 (broad region; genes not listed).
- chr9:23,690,104–78,330,093, 714 genes, copy number 5–10 (broad region; genes not listed).
- chr9:82,979,590–110,172,512, 480 genes, copy number 5–8 (within-gene range 2–8) (broad region; genes not listed).
- chr9:110,024,881–115,744,330, 103 genes, copy number 5 (broad region; genes not listed).
- chr9:119,935,053–138,253,217, 553 genes, copy number 5–7 (broad region; genes not listed).
- chr11:64,823,052–79,612,300, 575 genes, copy number 5 (within-gene range 5–6) (broad region; genes not listed).
- chr17:19,678,288–32,997,877, 435 genes, copy number 5–9 (broad region; genes not listed).
- chr17:34,479,272–51,521,401, 859 genes, copy number 5–9 (broad region; genes not listed).
- chr17:54,477,796–83,240,804, 896 genes, copy number 5–7 (broad region; genes not listed).
- chr18:45,034–7,301,153, 149 genes, copy number 5–10 (broad region; genes not listed).
- chr18:8,406,761–24,986,980, 299 genes, copy number 5–9 (within-gene range 3–9) (broad region; genes not listed).
- chr18:25,016,434–37,762,131, 168 genes, copy number 5–7 (within-gene range 1–9) (broad region; genes not listed).
- chr20:34,689,097–38,923,024, 140 genes, copy number 5–6 (within-gene range 4–6) (broad region; genes not listed).
- chr20:43,894,720–55,075,140, 264 genes, copy number 5–9 (broad region; genes not listed).
- chr21:15,928,296–23,490,724, 92 genes, copy number 5–9 (broad region; genes not listed).
- chr22:15,282,557–18,518,161, 127 genes, copy number 5–13 (broad region; genes not listed).
- chr22:48,866,770–50,801,309, 77 genes, copy number 7 (broad region; genes not listed).

Autosomal genes at a single copy (total copy number 1): 583. Sex chromosomes are excluded from the deletion and amplification lists above because the expected copy number there depends on sex.
